Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5109, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5109-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: KIDNEY, LEFT, LEFT RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA, CLEAR CELL TYPE WITH FOCAL AREAS WITH A TUBULO-PAPILLARY GROWTH PATTERN AND HIGH GRADE MORPHOLOGY.
- B. THERE IS EXTENSIVE NECROSIS.
- C. THE FUHRMAN NUCLEAR GRADE IS 4.
- D. THE CARCINOMA MEASURES 9.5 CM IN GREATEST DIMENSION.
- E. THE CARCINOMA EXTENSIVELY INFILTRATES INTO THE RENAL PARENCHYMA AND ALSO INVOLVES THE PERIRENAL AND PERIPELVIC FAT.
- F. LYMPHOVASCULAR INVASION IS IDENTIFIED.
- G. THE CARCINOMA INVOLVES THE RENAL VEIN.
- H. ALL SURGICAL RESECTION MARGINS ARE NEGATIVE.
- I. ADRENAL IS NOT PRESENT.
- J. TNM STAGE: pT3b N1 Mx.
- K. NON-NEOPLASTIC KIDNEY WITH CHRONIC CHANGES INCLUDING TUBULAR ATROPHY AND INTERSTITIAL INFLAMMATION.

PART 2: LYMPH NODE, PERIAORTIC, EXCISION –

METASTATIC CARCINOMA INVOLVING AND COMPLETELY REPLACING ONE OF ONE LYMPH NODE.

Source: NCI Genomic Data Commons file bccf1cc2-3d3c-42ec-ab98-38045a8eefd3 (TCGA-B0-5109.85014344-65F6-48B5-AED7-6FE36AD0A31E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).